Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACW, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACW-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : HCC

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Laparoscopic segmentectomy (segment 2)

Organ: Liver (15.0 x 6.0 x 4.5 cm, 142.5 gm)

Lesion: Hepatic mass

Size: 2.0 x 1.8 x 1.5 cm

Cut surface: Encapsulated, yellowish tan, round and solid with central necrosis

Gross type: Multinodular confluent

Extent: Confined to the capsule

Resection margin: Not involved, grossly (safety margin: 1.2 cm)

Remaining parenchyme: Cirrhosis

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, mass of liver x 4

RM, mass with resection margin x 1

A, nontumorous liver parenchyme x 1

ICD O-3

Carcinoma, hepatocellular NOS 8170/3

Site Liver C22.0

JP 5/19/14

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-steiner grade

The worst differentiation III

The major differentiation III

Histologic type: Trabecular

Cell type: Hepatic clear cell and solid pattern

Fatty change: No

Cholangiocarcinoma: No

Fibrous capsule formation: Yes

Capsular infiltration: Yes

Septum formation: Yes

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Lymphovascular invasion: Yes

Bile duct invasion: No

Remaining liver parenchyme: Cirrhosis

NOT reported. Gross:

Peritoneal fluid, smear, negative

[page 2 of 2]
Pleural fluid, smear, inflammation

Pleural fluid, smear, negative

Peritoneal fluid, smear, negative

Pleural fluid, smear, negative

Pleural fluid, smear, negative

Pleural fluid, smear, negative

Pleural fluid, smear, negative

Stomach, prepylorus, scopic, no pathologic finding

liver,ectomy,hepatocellular carcinoma,cirrhosis

T56000, P10, M81703, M49500

DIAGNOSIS:

Liver, lateral segment, left, laparoscopic segmentectomy:

Hepatocellular carcinoma

Cirrhosis

Suggestion :

Source: NCI Genomic Data Commons file d86a35ca-e339-4cc3-9ca7-860e24020ec4 (TCGA-DD-AACW.04474C44-102B-4514-BC48-468B9ED478A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).